Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A7M8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A7M8-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected
Time Reported
Order Number
Status

Final

Time Received
Time Transmitted
Ordering Provider
Relevant Information
Location

Copied To

Report Patient
Demographics (for
verification purposes) Date of Birth:
Sex:

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
Left liver

Clinical Information
HCC segment 2. Two other lesions segment 3.

Diagnosis

Liver, Partial Hepatectomy:

- Well-differentiated hepatocellular carcinoma arising in a background of cirrhosis and hemosiderosis.
- See synoptic report for details.

Reported by:

Electronically signed by:
Verified:

Synoptic Report

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GI: Well differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

ICD-O-3

Carcinoma, hepatocellular
8170/3

Site: Liver
C22.0

JW 9/26/13

[page 2 of 2]
*VENOUS (LARGE VESSEL) INVASION (V):
*Absent
*ADDITIONAL PATHOLOGIC FINDINGS:
*Cirrhosis/fibrosis
*Iron overload
At least one hemangioma

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 2.1 cm

TUMOR FOCALITY:

Solitary (specify location): Segment 2

Gross Description

Received fresh is a single specimen contained in the requisition and specimen container are labelled with the patient's name, The cassette and are labelled with the Surgical Number

The container is designated "left liver". The specimen consists of a partial hepatectomy specimen weighing 666.1 g and measuring 23.0 x 12.0 x 6.0 cm. The resection margin is painted blue. The outer surface has a vaguely nodular appearance. On sectioning, the liver parenchyma has a micronodular, cirrhotic appearance with an orange/brown discoloration. Three potential lesions are identified. The largest is a circumscribed soft tan/yellow nodule approaching the painted resection margin and this measures 2.1 cm in diameter. A second blood-filled cystic lesion is seen at the opposite end of the resection specimen and it measures 0.9 cm in diameter. It approximates the capsule. Another small hemorrhagic area is seen near to this second lesion, but it is unclear whether or not this represents a separate lesion. There is an apparent fullness to one of the portal tract areas adjacent to the inked resection margin. Otherwise, no other mass lesions are identified.

A1-A3 largest nodule
A4-A5 cystic hemorrhagic lesions
A6 capsule
A7-A8 bile duct fullness
A9 non-neoplastic liver

Pathologist Comment

Accession Number
Encounter Number
Patient Location

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file 2cb43b9d-f098-4f07-9769-7eb4833b1f7d (TCGA-G3-A7M8.77483096-0271-4EBD-BC39-2232A3DEFF69.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).